Somatic mutation profile of tumor specimen TCGA-21-1081-01A (aliquot TCGA-21-1081-01A-01D-1521-08) from TCGA case TCGA-21-1081, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.7 years (25,440 days).
Specimen TCGA-21-1081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 277fdc59-4a88-4b76-a13c-78a7d4522f30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1081-10B (Blood Derived Normal), aliquot TCGA-21-1081-10B-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aea39a63-105b-40bc-96d8-978ef60d7e58

The open-access MAF lists 213 somatic variants for this specimen: 164 protein-altering or splice-affecting, 41 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 41, Nonsense Mutation 10, Intron 5, Frame Shift Del 4, Splice Site 3, 5'Flank 2, In Frame Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INTU | c.396del p.N132Kfs*11 | Frame Shift Del (DEL) | VAF 50/112 reads (45%) | catalogued as rs1553970289, CD166923; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AC100868.1 | c.1509C>A p.F503L | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as COSV51844117; called by muse, mutect2, varscan2
- ADAMTS19 | c.1703C>A p.T568K | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV50752175; called by muse, mutect2, varscan2
- AMOTL2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV51439302; called by muse, mutect2, varscan2
- APCS | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54817288; called by muse, mutect2, varscan2
- ARHGAP39 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52770972; called by muse, mutect2, varscan2
- ATP11C | c.1645C>G p.R549G | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59559449, COSV59565145; called by muse, mutect2, varscan2
- B3GALT6 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.04); catalogued as COSV55419497; called by muse, mutect2, varscan2
- BLNK | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV56411479, COSV99813569; called by muse, mutect2, varscan2
- BRINP1 | c.216C>A p.Y72* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV56301641; called by muse, mutect2, varscan2
- C10orf88 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 64/140 reads (46%) | catalogued as COSV64404015; called by muse, mutect2, varscan2
- C2CD5 | c.1135A>T p.I379F | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61724913; called by muse, mutect2, varscan2
- C2CD5 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs1384283126, COSV61724922; called by muse, mutect2, varscan2
- CASZ1 | c.1508C>T p.T503M | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59735448; called by muse, mutect2, varscan2
- CCDC115 | c.308G>T p.R103M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV52091851; called by muse, mutect2, varscan2
- CCDC116 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as rs771117152, COSV53037972; called by muse, mutect2, varscan2
- CCDC39 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs780264719, COSV56477777; ClinVar: uncertain significance; called by muse, mutect2
- CDK14 | c.265C>G p.Q89E (on ENST00000380050 / NM_001287135.2; = p.Q71E on NM_012395.3) | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.68); catalogued as COSV56036668; called by muse, mutect2, varscan2
- CDKN1A | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs779717089, COSV55187110, COSV55190712; called by muse, mutect2, varscan2
- CLPTM1L | c.1276A>T p.K426* | Nonsense Mutation (SNP) | VAF 52/122 reads (43%) | catalogued as COSV57990761; called by muse, mutect2, varscan2
- CPS1 | c.3888G>T p.L1296F | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.676); catalogued as COSV51811972; called by muse, mutect2, varscan2
- CPVL | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771212555, COSV55303374; called by muse, mutect2
- CREBBP | c.3893A>G p.Y1298C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); catalogued as rs773159964, COSV52125779; called by muse, mutect2, varscan2
- CREBBP | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 144/390 reads (37%) | catalogued as CD021194, COSV52122968; called by muse, varscan2
- CRIM1 | c.2656A>G p.I886V | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.891); catalogued as rs748998611, COSV54865147; called by muse, mutect2, varscan2
- CRYM | c.512A>T p.K171I | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV54831628; called by muse, mutect2, varscan2
- CUX1 | c.2849G>C p.R950P | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52898145, COSV52901564; called by muse, mutect2, varscan2
- CXCR4 | c.842A>G p.H281R | Missense Mutation (SNP) | VAF 195/939 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.078); catalogued as COSV54013044; called by muse, mutect2, varscan2
- CYP21A2 | c.1197G>A p.W399* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as COSV100926026; called by muse, mutect2, varscan2
- CYP24A1 | c.937A>C p.K313Q | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV53774806; called by muse, mutect2, varscan2
- DACH2 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64170758; called by muse, mutect2, varscan2
- DHRSX | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.072); catalogued as rs1432291620, COSV58130102; called by muse, mutect2
- DMD | c.3073A>T p.I1025F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV63759141; called by muse, mutect2
- DNAH8 | c.10228C>A p.Q3410K | Missense Mutation (SNP) | VAF 82/146 reads (56%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as COSV59451081; called by muse, mutect2, varscan2
- DOCK10 | c.4076G>A p.R1359K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.977); catalogued as COSV51412465; called by muse, mutect2, varscan2
- DOCK4 | c.3677A>G p.Y1226C | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69854662; called by muse, mutect2, varscan2
- ELP5 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV59708761; called by muse, mutect2, varscan2
- EVX1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV56085103; called by muse, mutect2, varscan2
- FAT1 | c.6939A>C p.E2313D | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.307); catalogued as COSV71674427; called by muse, mutect2, varscan2
- FBXO28 | c.713T>G p.V238G | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs754071147, COSV64800572; called by muse, mutect2, varscan2
- FLNC | c.6805G>A p.G2269S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as rs1300257972, COSV57956846; called by muse, mutect2, varscan2
- FOXH1 | c.851T>C p.I284T | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV56761229; called by muse, mutect2, varscan2
- FRY | c.8027C>A p.A2676D | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV66571189; called by muse, mutect2, varscan2
- GABRA2 | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 123/251 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as COSV62913537; called by muse, mutect2, varscan2
- GAD1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60151605, COSV60152627; called by muse, mutect2, varscan2
- GCM2 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65275751; called by muse, varscan2
- GIMAP1 | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56188383; called by muse, mutect2, varscan2
- GUSB | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 109/395 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs765983374, COSV59222148; called by muse, mutect2, varscan2
- HCCS | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV58239183; called by muse, mutect2, varscan2
- HCRTR2 | c.762+2T>A p.X254_splice | Splice Site (SNP) | VAF 24/61 reads (39%) | catalogued as COSV63796171; called by muse, mutect2, varscan2
- HLTF | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59501086; called by muse, mutect2, varscan2
- HNRNPA3 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 31/140 reads (22%) | catalogued as COSV66820681, COSV66820724; called by muse, mutect2, varscan2
- ITGB4 | c.1764C>T p.G588= | Splice Region (SNP) | VAF 78/138 reads (57%) | catalogued as COSV52326846; called by muse, mutect2, varscan2
- ITSN1 | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs768901601, COSV66082643; called by muse, mutect2, varscan2
- KCNH7 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); catalogued as COSV59798742; called by muse, mutect2, varscan2
- KCNK2 | c.1066C>T p.Q356* (on ENST00000444842 / NM_001017425.3; = p.Q341* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 25/173 reads (14%) | catalogued as COSV67206474; called by muse, mutect2, varscan2
- KCNN4 | c.983A>C p.H328P | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV53455747; called by muse, mutect2, varscan2
- KCTD10 | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57327103; called by muse, mutect2, varscan2
- KDM5A | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV66991302; called by muse, mutect2, varscan2
- KIAA0232 | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56925782; called by muse, mutect2, varscan2
- KIF9 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV55520023; called by muse, mutect2, varscan2
- KLHL17 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs765312887, COSV58532099; called by muse, mutect2, varscan2
- KRTAP12-4 | c.56G>A p.C19Y | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs376121988, COSV59964804; called by muse, mutect2, varscan2
- LAMA1 | c.5980C>T p.L1994F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.394); catalogued as COSV67538156; called by muse, mutect2, varscan2
- LCA5 | c.369G>C p.Q123H | Missense Mutation (SNP) | VAF 99/214 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.054); catalogued as COSV63971615, COSV63972540; called by muse, mutect2, varscan2
- MAVS | c.402A>T p.R134S | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV63927042; called by muse, mutect2
- MGAT1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | PolyPhen probably damaging (0.986); catalogued as COSV57134243; called by muse, mutect2, varscan2
- MROH1 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1196845588; called by muse, mutect2, varscan2
- MTBP | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV59963426; called by muse, mutect2, varscan2
- MYH1 | c.4235A>T p.N1412I | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV56849600; called by muse, mutect2, varscan2
- MYO1A | c.722C>G p.A241G | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV55654457; called by muse, mutect2, varscan2
- MYT1L | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV67721601; called by muse, mutect2, varscan2
- NLGN1 | c.808C>A p.L270M | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64335336; called by muse, mutect2, varscan2
- NLRP11 | c.1492C>A p.L498I | Missense Mutation (SNP) | VAF 79/312 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV64087605; called by muse, mutect2, varscan2
- NLRP13 | c.267C>A p.F89L | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as COSV61622136, COSV61622342; called by muse, mutect2, varscan2
- OAZ3 | c.282C>G p.D94E | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100162391; called by muse, varscan2
- OR4C11 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56353580; called by muse, mutect2, varscan2
- OR4C6 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as COSV58604314; called by muse, mutect2, varscan2
- OR52B4 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV68769017; called by muse, mutect2, varscan2
- OR5H14 | c.903C>A p.F301L | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71194010; called by muse, mutect2
- OR5H6 | c.908C>G p.P303R (on ENST00000642105; = p.P287R on NM_001005479.2) | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV101051739, COSV67351583; called by muse, mutect2
- OR6K3 | c.149T>A p.I50N (on ENST00000368146; = p.I34N on NM_001005327.2) | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV63745729; called by muse, mutect2, varscan2
- OR6K6 | c.1012G>T p.A338S (on ENST00000368144; = p.A314S on NM_001005184.1) | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as rs760406673, COSV63744271; called by muse, mutect2, varscan2
- OR9A2 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV63306667; called by muse, mutect2, varscan2
- OSR2 | c.371C>A p.A124D | Missense Mutation (SNP) | VAF 113/326 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52557178; called by muse, varscan2
- PCARE | c.1570C>A p.P524T | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV59055211; called by muse, mutect2, varscan2
- PDE4DIP | c.3029G>A p.R1010K | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs782670958, COSV57699093; called by muse, mutect2, varscan2
- PDE4DIP | c.3030G>T p.R1010S | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as COSV57699079, COSV57731045; called by muse, mutect2, varscan2
- PGLYRP2 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs780886152, COSV52994408; called by muse, mutect2, varscan2
- PHYH | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1407156746, COSV53816160; called by muse, mutect2, varscan2
- PIK3CD | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV63129068; called by muse, varscan2
- PIK3CD | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs1384520389, COSV63129074; called by muse, mutect2, varscan2
- PKNOX2 | c.571A>G p.I191V | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV53546902; called by muse, mutect2, varscan2
- PLIN4 | c.2127G>C p.K709N (on ENST00000301286; = p.K724N on NM_001367868.2) | Missense Mutation (SNP) | VAF 81/547 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs370698276; called by muse, mutect2, varscan2
- PLXNA4 | c.4165C>T p.L1389F | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562894072, COSV58130856; called by muse, mutect2, varscan2
- PLXNA4 | c.1744T>A p.Y582N | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV58130876; called by muse, mutect2, varscan2
- PPP1R3A | c.280T>A p.L94I | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.615); catalogued as COSV52883939; called by muse, mutect2
- PPP2R2C | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs781182513, COSV59444662; called by muse, mutect2, varscan2
- PRKN | c.599A>C p.H200P | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV58230489; called by muse, mutect2, varscan2
- PRSS22 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50720886, COSV50721856; called by muse, mutect2, varscan2
- PSG8 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 95/658 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV60612328; called by muse, mutect2, varscan2
- PUSL1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1467480577, COSV60088631; called by muse, mutect2, varscan2
- PXDNL | c.1505A>T p.Q502L | Missense Mutation (SNP) | VAF 55/325 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV62488616; called by muse, mutect2, varscan2
- RASSF9 | c.1141A>G p.R381G | Missense Mutation (SNP) | VAF 124/257 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV63434042; called by muse, mutect2, varscan2
- RHAG | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 123/298 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV57704643; called by muse, mutect2, varscan2
- RP1 | c.1970T>G p.L657R | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.174); catalogued as COSV55118137; called by muse, mutect2, varscan2
- RPS2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 41/121 reads (34%) | catalogued as COSV51910120, COSV51910970; called by muse, mutect2, varscan2
- RTP4 | c.656C>G p.P219R | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV52018506; called by muse, mutect2
- RXFP1 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57050806; called by muse, mutect2, varscan2
- SEMA3E | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV57092670; called by muse, mutect2, varscan2
- SEMA4F | c.749T>C p.F250S | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60283531; called by muse, varscan2
- SETDB1 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV54984020; called by muse, mutect2, varscan2
- SF3A3 | c.1170+1G>C p.X390_splice | Splice Site (SNP) | VAF 35/128 reads (27%) | catalogued as COSV65955906; called by muse, mutect2, varscan2
- SGIP1 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs202205354, COSV52766473, COSV52770350; called by muse, mutect2
- SIRT3 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV61501117; called by muse, mutect2, varscan2
- SLC12A1 | c.1123A>T p.T375S | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV57709879; called by muse, mutect2, varscan2
- SLC26A7 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV52594748; called by muse, mutect2, varscan2
- SLC2A4RG | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs758701260, COSV55510709; called by muse, mutect2, varscan2
- SLC7A10 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs375602222; called by muse, mutect2, varscan2
- SLC9A7 | c.1567A>G p.I523V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60380557; called by muse, mutect2, varscan2
- SLX4 | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV53563225, COSV53564626; called by muse, mutect2, varscan2
- SOGA3 | c.2488G>C p.D830H | Missense Mutation (SNP) | VAF 104/193 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64106844; called by muse, mutect2, varscan2
- SPAG16 | c.1298A>T p.E433V | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.855); catalogued as COSV59097269; called by muse, varscan2
- SYNE1 | c.19982A>G p.Q6661R (on ENST00000367255 / NM_182961.4; = p.Q6590R on NM_033071.3) | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54998164; called by muse, mutect2, varscan2
- SYNE2 | c.3412A>G p.T1138A | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59952957; called by muse, mutect2, varscan2
- TAF1L | c.4352A>G p.E1451G | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV54262814; called by muse, mutect2, varscan2
- TDRD5 | c.2921C>A p.P974H | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54243920; called by muse, mutect2, varscan2
- TECPR2 | c.2813C>T p.S938F | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV63970971; called by muse, mutect2, varscan2
- TECTA | c.3284G>T p.R1095L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.815); catalogued as rs771933470, COSV50716628, COSV99881136; called by muse, mutect2, varscan2
- TLE3 | c.2024C>A p.A675D | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58170051; called by muse, mutect2, varscan2
- TMEM131 | c.1654A>G p.I552V | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as rs773200720, COSV51777232; called by muse, mutect2, varscan2
- TMEM18 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as rs201517976; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.992); catalogued as COSV64101257; called by muse, mutect2
- TNKS1BP1 | c.1514A>T p.E505V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64101261; called by muse, mutect2
- TNRC18 | c.7355G>A p.R2452Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs777475021, COSV60307859; called by muse, mutect2, varscan2
- TOMM70 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52523621; called by muse, mutect2, varscan2
- TP53 | c.404del p.C135Sfs*35 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as COSV52675774, COSV52680475, COSV52702460, COSV53452020; called by mutect2, varscan2
- TRMT10C | c.619T>G p.F207V | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59306008; called by muse, mutect2
- TRRAP | c.4252A>C p.I1418L | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV62845737; called by muse, mutect2
- TTN | c.100055C>T p.T33352M (on ENST00000591111; = p.T25928M on NM_003319.4) | Missense Mutation (SNP) | VAF 54/133 reads (41%) | PolyPhen benign (0.003); catalogued as rs368945564, COSV60067083; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.70856A>C p.Q23619P (on ENST00000591111; = p.Q16195P on NM_003319.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | PolyPhen possibly damaging (0.732); catalogued as COSV60104076; called by muse, mutect2, varscan2
- UBXN11 | c.1417C>T p.R473* (on ENST00000374221 / NM_183008.2; = p.R440* on NM_145345.2) | Nonsense Mutation (SNP) | VAF 84/253 reads (33%) | catalogued as rs746374879, COSV53326509, COSV53329804; called by muse, varscan2
- UGT3A2 | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV56930943; called by muse, mutect2, varscan2
- ULK4 | c.210C>A p.H70Q | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57210561; called by muse, mutect2, varscan2
- USH2A | c.4687C>A p.P1563T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56371300; called by muse, mutect2, varscan2
- UTY | c.3846G>T p.E1282D | Missense Mutation (SNP) | VAF 61/91 reads (67%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV58870127; called by muse, mutect2, varscan2
- VCPIP1 | c.3188G>T p.S1063I | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV60047614; called by muse, mutect2, varscan2
- WDR62 | c.391-2A>G p.X131_splice | Splice Site (SNP) | VAF 38/149 reads (26%) | catalogued as COSV54335495; called by muse, mutect2, varscan2
- WDR75 | c.2028A>C p.K676N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.582); catalogued as COSV59105764; called by muse, mutect2, varscan2
- XPA | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as rs200218050, COSV64305250, COSV64305306; called by muse, mutect2, varscan2
- ZDHHC14 | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV58194509; called by muse, mutect2, varscan2
- ZFHX4 | c.8299C>A p.L2767I | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); catalogued as COSV50893292; called by muse, mutect2, varscan2
- ZFHX4 | c.9347C>A p.S3116Y | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50726488, COSV50893972, COSV51488364; called by muse, mutect2, varscan2
- ZNF479 | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58639221; called by muse, mutect2, varscan2
- ZNF496 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 42/205 reads (20%) | catalogued as COSV54177905; called by muse, mutect2, varscan2
- ZNF560 | c.1840G>C p.D614H | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.749); catalogued as COSV56868286; called by muse, mutect2, varscan2
- ZNF570 | c.1459C>G p.Q487E | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.475); catalogued as COSV57579303; called by muse, mutect2, varscan2
- ZNF608 | c.3781G>C p.D1261H | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV60438273; called by muse, mutect2, varscan2
- ZNF765 | c.1406A>G p.N469S | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); catalogued as rs761063655, COSV67182673; called by muse, mutect2, varscan2
- ZPLD1 | c.614C>G p.P205R (on ENST00000466937 / NM_001329788.1; = p.P221R on NM_175056.2) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100083556, COSV60353999; called by muse, mutect2, varscan2
- COLEC11 | c.524del p.G175Afs*3 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- IGKV2D-30 | c.137G>C p.S46T | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- RELT | c.904_906del p.K302del | In Frame Del (DEL) | VAF 10/70 reads (14%) | called by pindel, varscan2
- ZNF260 | c.986_1001del p.D329Vfs*18 | Frame Shift Del (DEL) | VAF 25/282 reads (9%) | called by mutect2, pindel
- ABCC1 | c.1461C>T p.T487= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV60686976; called by muse, mutect2
- ANKRD27 | c.1767G>A p.A589= | Silent (SNP) | VAF 251/650 reads (39%) | catalogued as rs757621638, COSV60131404; called by muse, mutect2, varscan2
- ATP7B | c.1921T>C p.L641= | Silent (SNP) | VAF 110/190 reads (58%) | catalogued as COSV54439263; called by muse, mutect2, varscan2
- BRPF1 | c.2769C>T p.H923= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as rs369407011; called by muse, mutect2, varscan2
- CD1E | c.736C>A p.R246= | Silent (SNP) | VAF 61/215 reads (28%) | catalogued as rs560510473, COSV63769947, COSV63771242; called by muse, mutect2, varscan2
- CDH18 | c.1824G>A p.S608= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as rs767007708, COSV56920030; called by muse, mutect2, varscan2
- CDH22 | c.1860C>T p.A620= | Silent (SNP) | VAF 39/57 reads (68%) | catalogued as COSV64837830; called by muse, mutect2, varscan2
- CEP170B | c.939C>T p.T313= (on ENST00000453495; = p.T242= on NM_015005.3) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV69023631; called by muse, mutect2
- CNTN3 | c.2526C>T p.Y842= | Silent (SNP) | VAF 119/215 reads (55%) | catalogued as COSV55173159; called by muse, mutect2, varscan2
- DEFB125 | c.462T>A p.T154= | Silent (SNP) | VAF 80/520 reads (15%) | catalogued as COSV66703333; called by muse, varscan2
- DNAH7 | c.435T>C p.D145= | Silent (SNP) | VAF 105/292 reads (36%) | catalogued as rs762094488, COSV56767572; called by muse, varscan2
- EIF2AK3 | c.1251C>A p.V417= | Silent (SNP) | VAF 35/178 reads (20%) | catalogued as COSV57548291, COSV57553130; called by muse, mutect2, varscan2
- EIF3A | c.3873C>T p.D1291= | Silent (SNP) | VAF 56/322 reads (17%) | catalogued as rs774454537, COSV64961656; called by muse, mutect2, varscan2
- FMR1 | c.1449A>G p.R483= | Silent (SNP) | VAF 53/86 reads (62%) | catalogued as COSV54424469; called by muse, mutect2, varscan2
- FOXJ3 | c.1497T>G p.S499= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV62362666; called by muse, varscan2
- FRG2C | c.789T>A p.P263= | Silent (SNP) | VAF 46/213 reads (22%) | called by muse, mutect2, varscan2
- INTS1 | c.669C>T p.P223= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs552027973, COSV67176583, COSV67177780; called by muse, mutect2, varscan2
- ITGB8 | c.504C>T p.S168= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as rs200718910; called by muse, mutect2, varscan2
- LARS1 | c.3447G>T p.V1149= (on ENST00000394434 / NM_020117.11; = p.V1122= on NM_016460.3) | Silent (SNP) | VAF 105/205 reads (51%) | catalogued as COSV50977987; called by muse, mutect2, varscan2
- LDHD | c.1203C>A p.I401= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs571838219, COSV55579997, COSV55581053; called by muse, mutect2, varscan2
- MCF2 | c.70T>C p.L24= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV58476896, COSV58478333; called by muse, mutect2, varscan2
- MYPN | c.2583G>A p.A861= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs1203254918, COSV62734592; called by muse, mutect2, varscan2
- NAV3 | c.2646C>T p.D882= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as COSV57083675; called by muse, mutect2, varscan2
- OR2L2 | c.564C>T p.C188= | Silent (SNP) | VAF 73/450 reads (16%) | catalogued as rs1447293549, COSV63553445; called by muse, mutect2, varscan2
- PBDC1 | c.147C>G p.V49= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV64895822; called by muse, mutect2, varscan2
- PDGFRA | c.1605G>A p.L535= | Silent (SNP) | VAF 73/175 reads (42%) | catalogued as COSV57268900; called by muse, mutect2, varscan2
- PKD1 | c.11211G>A p.G3737= (on ENST00000262304 / NM_001009944.3; = p.G3736= on NM_000296.4) | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV51917493; called by muse, mutect2, varscan2
- PSMD2 | c.1935C>T p.D645= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as COSV59530051; called by muse, mutect2
- RASGRF1 | c.813G>C p.R271= | Silent (SNP) | VAF 97/170 reads (57%) | catalogued as COSV69179510; called by muse, mutect2, varscan2
- RPS6KA6 | c.1125G>A p.L375= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV53120605; called by muse, mutect2, varscan2
- SBF1 | c.3597C>T p.S1199= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as rs754805260, COSV62367461; called by muse, mutect2, varscan2
- SCN9A | c.1713C>T p.A571= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as rs200876333, COSV57611883; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLA | c.201T>G p.G67= (on ENST00000338087 / NM_001045556.3; = p.G107= on NM_006748.4) | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as COSV55078796; called by muse, mutect2, varscan2
- SNX31 | c.48G>A p.A16= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs556203287, COSV61263344; called by muse, mutect2, varscan2
- STEAP2 | c.1452G>A p.P484= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs201134508, COSV55288941; called by muse, mutect2, varscan2
- STX5 | c.285C>T p.T95= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as COSV53679738; called by muse, mutect2, varscan2
- TENM3 | c.1854G>C p.G618= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV69309735; called by muse, mutect2, varscan2
- THSD7A | c.504T>A p.P168= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV70265657, COSV70269973; called by muse, mutect2, varscan2
- ZNF311 | c.348G>C p.L116= | Silent (SNP) | VAF 72/274 reads (26%) | catalogued as COSV65853139; called by muse, varscan2
- ZNF430 | c.273A>T p.G91= | Silent (SNP) | VAF 62/132 reads (47%) | catalogued as COSV55110160; called by muse, mutect2, varscan2
- ZSWIM4 | c.1281C>T p.A427= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as rs1238823693, COSV54322403; called by muse, mutect2, varscan2
- COP1 | c.2133+18469G>T | Intron (SNP) | VAF 71/206 reads (34%) | catalogued as COSV100442935, COSV100443102; called by muse, mutect2, varscan2
- GSG1 | c.481+72C>T | Intron (SNP) | VAF 45/104 reads (43%) | catalogued as rs768195450, COSV60970956; called by muse, mutect2, varscan2
- LYSMD4 | c.282+316A>T | Intron (SNP) | VAF 78/152 reads (51%) | catalogued as COSV100230558; called by muse, mutect2, varscan2
- MIR18B | n.28G>C | RNA (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559217 C>A | 5'Flank (SNP) | VAF 40/129 reads (31%) | called by muse, varscan2
- RNU7-174P | chr8:80559218 C>A | 5'Flank (SNP) | VAF 38/127 reads (30%) | catalogued as rs1271623182; called by muse, varscan2
- TRAK1 | c.1963+267G>A | Intron (SNP) | VAF 241/460 reads (52%) | catalogued as COSV100409837; called by muse, mutect2, varscan2
- TTN | c.34265-4184C>A | Intron (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100600122; called by mutect2, varscan2
